Somatic mutation profile of tumor specimen TCGA-Y6-A8TL-01A (aliquot TCGA-Y6-A8TL-01A-21D-A377-08) from TCGA case TCGA-Y6-A8TL, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.1 years (23,776 days).
Specimen TCGA-Y6-A8TL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01fdd4dd-2fb1-41c4-9a77-f782d0d1092e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Y6-A8TL-10A (Blood Derived Normal), aliquot TCGA-Y6-A8TL-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d57c6a7a-17fc-461c-b982-6ac380e5a2b7

The open-access MAF lists 29 somatic variants for this specimen: 26 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 21, Nonsense Mutation 3, Silent 3, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.391T>G p.W131G | Missense Mutation (SNP) | VAF 49/161 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as rs1057519968, COSV61652911, COSV61653817; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AGBL5 | c.1625C>G p.P542R | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100549268; called by muse, mutect2, varscan2
- ALG5 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV53505610; called by muse, mutect2
- AP4B1 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1449161416, COSV99870441; called by muse, mutect2, varscan2
- CDCA2 | c.1043A>T p.N348I | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV100399017; called by muse, mutect2, varscan2
- CDH6 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV54068530; called by muse, mutect2
- CFHR2 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as rs1442182384, COSV100804371, COSV66380555; called by muse, mutect2, varscan2
- CHD3 | c.3059A>G p.N1020S | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100391450; called by muse, mutect2, varscan2
- CLN8 | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV100486095; called by muse, varscan2
- COQ5 | c.29G>A p.W10* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99942424; called by muse, mutect2, varscan2
- CORO2B | c.1101C>G p.D367E | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV104380024, COSV99963576; called by muse, mutect2
- CTNNAL1 | c.1797C>G p.N599K | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.136); catalogued as COSV100336654; called by muse, mutect2, varscan2
- FGB | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100122514; called by muse, mutect2, varscan2
- GDF10 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs782623944; called by muse, mutect2, varscan2
- GOLM2 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100247761; called by muse, mutect2
- KRT4 | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 35/95 reads (37%) | catalogued as rs1284159580, COSV104395655, COSV53405642; called by muse, mutect2, varscan2
- MAP2K4 | c.174G>C p.R58S | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100796396; called by muse, mutect2
- NBN | c.1699T>C p.F567L | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1554558312, COSV99619854; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POC1B | c.452A>C p.K151T | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1351222463, COSV100544395; called by muse, mutect2, varscan2
- PRRT2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs754897123, COSV54881782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCD3 | c.1072C>A p.R358S | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.066); catalogued as COSV99606514; called by muse, mutect2, varscan2
- TOX4 | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753297484, COSV99398472; called by muse, mutect2, varscan2
- ZNF507 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV100322016; called by muse, mutect2, varscan2
- EIF4G3 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- SEPTIN4 | c.1139del p.P380Qfs*29 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- TPP1 | c.1537dup p.A513Gfs*5 | Frame Shift Ins (INS) | VAF 103/413 reads (25%) | called by mutect2, pindel, varscan2
- CSMD1 | c.7824G>A p.T2608= (on ENST00000520002; = p.T2607= on NM_033225.6) | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs746936196, COSV100144233, COSV100151547; called by muse, mutect2, varscan2
- FGD2 | c.1494A>G p.E498= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV99236440; called by muse, mutect2
- MAP1B | c.3453G>A p.E1151= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV57104748, COSV99702336; called by muse, mutect2
